MMRF case MMRF_1038 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0094e07c-1595-402e-9d38-68b9cac71e7b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Dead; Days to death: 1,753 days (4.8 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.1 years (25,255 days); ISS stage: III; Days to last known disease status: 1,753 days (4.8 years); Days to last follow up: 1,753 days (4.8 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 1,735 days (4.8 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 9 days; Days to treatment end: 1,738 days (4.8 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,753.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -30 (ECOG 1): M Protein 3.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 89.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.361 mg/dL; Immunoglobulin G 63.1 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 6.71 µg/mL; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 10.5 ×10⁹/L; Absolute Neutrophil 5.89 ×10⁹/L; Platelets 310 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 3.15 mmol/L; Albumin 36 g/L; Total Protein 9.9 g/dL; Glucose 7.26 mmol/L; C-Reactive Protein 0.53 mg/dL.
- Day 118 (ECOG 1): M Protein 0.4 g/dL; Immunoglobulin G 6.33 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.42 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 7.95 ×10⁹/L; Absolute Neutrophil 4.62 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 7.81 mmol/L.
- Day 174 (ECOG 1): M Protein 0.2 g/dL; Immunoglobulin G 4.72 g/L; Immunoglobulin A 2.08 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.05 ×10⁹/L; Absolute Neutrophil 2.09 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.08 mmol/L; Albumin 38 g/L; Total Protein 5.6 g/dL; Glucose 6.44 mmol/L.
- Day 258: M Protein 0 g/dL; Immunoglobulin G 3.75 g/L; Immunoglobulin A 2.28 g/L; Immunoglobulin M 0.46 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 2.51 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 5.6 g/dL; Glucose 6 mmol/L.
- Day 340 (ECOG 2): M Protein 0 g/dL; Immunoglobulin G 3.33 g/L; Immunoglobulin A 2.64 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 6.39 ×10⁹/L; Absolute Neutrophil 3.54 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 7.2 g/dL; Glucose 6.05 mmol/L.
- Day 429 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 3.03 g/L; Immunoglobulin A 2.58 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.39 ×10⁹/L; Absolute Neutrophil 2.57 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 1.88 mmol/L; Albumin 38 g/L; Total Protein 5.7 g/dL; Glucose 4.84 mmol/L.
- Day 494: M Protein 0 g/dL; Immunoglobulin G 3.02 g/L; Immunoglobulin A 2.36 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.32 ×10⁹/L; Absolute Neutrophil 2.53 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 5.4 g/dL; Glucose 6.16 mmol/L.
- Day 621: M Protein 0 g/dL; Immunoglobulin G 3.31 g/L; Immunoglobulin A 2.76 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.28 ×10⁹/L; Absolute Neutrophil 2.23 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 5.5 g/dL; Glucose 5.89 mmol/L.
- Day 685: M Protein 0 g/dL; Immunoglobulin G 3.49 g/L; Immunoglobulin A 2.68 g/L; Immunoglobulin M 0.39 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.06 ×10⁹/L; Absolute Neutrophil 2.15 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 5.7 g/dL; Glucose 5.23 mmol/L.
- Day 783 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 3.27 g/L; Immunoglobulin A 3.22 g/L; Immunoglobulin M 0.4 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 5.82 ×10⁹/L; Absolute Neutrophil 2.96 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 5.3 g/dL; Glucose 5.23 mmol/L.
- Day 881: M Protein 0 g/dL; Immunoglobulin G 3.55 g/L; Immunoglobulin A 2.93 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 5.92 ×10⁹/L; Absolute Neutrophil 2.66 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 5.6 g/dL; Glucose 6.55 mmol/L.
- Day 951: M Protein 0 g/dL; Immunoglobulin G 3.27 g/L; Immunoglobulin A 2.74 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 6.97 ×10⁹/L; Absolute Neutrophil 4.36 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.1 mmol/L; Albumin 37 g/L; Total Protein 5.5 g/dL; Glucose 7.7 mmol/L.
- Day 1,056 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 3.87 g/L; Immunoglobulin A 3.59 g/L; Immunoglobulin M 0.48 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.46 ×10⁹/L; Absolute Neutrophil 2.09 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.08 mmol/L; Albumin 38 g/L; Total Protein 5.7 g/dL; Glucose 5.67 mmol/L.
- Day 1,119 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.41 mg/dL; Immunoglobulin G 4.57 g/L; Immunoglobulin A 3.85 g/L; Immunoglobulin M 0.53 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 7.04 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 276 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 6.22 mmol/L.
- Day 1,238 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.71 mg/dL; Immunoglobulin G 3.39 g/L; Immunoglobulin A 3.03 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 6.08 mmol/L; Leukocytes 7.89 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2 mmol/L; Albumin 36 g/L; Total Protein 5.4 g/dL; Glucose 5.45 mmol/L.
- Day 1,304 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 3.03 g/L; Immunoglobulin A 2.79 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 9.16 ×10⁹/L; Absolute Neutrophil 6.79 ×10⁹/L; Platelets 332 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.08 mmol/L; Albumin 35 g/L; Total Protein 5.4 g/dL; Glucose 5.01 mmol/L.
- Day 1,371: M Protein 0 g/dL; Immunoglobulin G 2.87 g/L; Immunoglobulin A 3.32 g/L; Immunoglobulin M 0.7 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 5.01 ×10⁹/L; Platelets 369 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 1.93 mmol/L; Albumin 24 g/L; Total Protein 4.1 g/dL; Glucose 6.16 mmol/L.
- Day 1,490: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 4.16 g/L; Immunoglobulin A 3.13 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 1.78 µg/mL; Hemoglobin 7.32 mmol/L; Leukocytes 5.17 ×10⁹/L; Absolute Neutrophil 2.45 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 4.57 mmol/L.
- Day 1,573 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.71 mg/dL; Immunoglobulin G 3.62 g/L; Immunoglobulin A 2.85 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 1.86 µg/mL; Hemoglobin 6.14 mmol/L; Leukocytes 4.62 ×10⁹/L; Absolute Neutrophil 3.19 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.13 mmol/L; Albumin 34 g/L; Total Protein 5.5 g/dL; Glucose 7.98 mmol/L.
- Day 1,672 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.25 mg/dL; Immunoglobulin G 4.13 g/L; Immunoglobulin A 4.6 g/L; Immunoglobulin M 0.65 g/L; Beta 2 Microglobulin 3.22 µg/mL; Hemoglobin 7.25 mmol/L; Leukocytes 7.46 ×10⁹/L; Absolute Neutrophil 2.79 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 5.89 mmol/L.

Other clinical attributes
- Day -30: Weight: 101 kg; Height: 180 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1038_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -30 days.
- Sample MMRF_1038_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -30 days.
